Somatic mutation profile of tumor specimen C3N-06997-01 (aliquot CPT0470670007) from CPTAC case C3N-06997, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.7 years (26,172 days).
Specimen C3N-06997-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebdc71a3-6014-4205-affa-7cd30c7cd051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06997-31 (Blood Derived Normal), aliquot CPT0470760006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e840cc4-b38c-41ad-a854-ff391cc83917

The open-access MAF lists 105 somatic variants for this specimen: 68 protein-altering or splice-affecting, 32 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 32, Nonsense Mutation 4, Intron 2, Splice Site 2, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/347 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACSM2A | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 123/335 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs565557207, COSV54589852; called by muse, mutect2, varscan2
- AKR1C2 | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 10/332 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs199757254; called by muse, mutect2
- ARHGAP39 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 272/730 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs770924292; called by muse, mutect2, varscan2
- ASXL3 | c.3387G>T p.L1129F | Missense Mutation (SNP) | VAF 197/484 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); catalogued as COSV52461333, COSV99323944; called by muse, mutect2, varscan2
- C10orf71 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 242/371 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV60510715; called by muse, mutect2, varscan2
- CYP24A1 | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 121/770 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV53772680; called by muse, mutect2, varscan2
- DSTYK | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 144/422 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs868788895, COSV65688701; called by muse, mutect2, varscan2
- HR | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 126/373 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs149278871, COSV100455585; called by muse, mutect2, varscan2
- INAVA | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 178/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1013509036, COSV66257787; called by mutect2, varscan2
- INTS13 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 120/340 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs760064652; called by muse, mutect2, varscan2
- ITLN2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 193/461 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs912358230, COSV63537517; called by muse, mutect2, varscan2
- JCAD | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 243/392 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs768950673; called by muse, mutect2, varscan2
- LRRIQ1 | c.2702C>T p.S901F | Missense Mutation (SNP) | VAF 150/372 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs773796685; called by muse, mutect2
- MALRD1 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 154/248 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs1271329005; called by muse, mutect2, varscan2
- MROH6 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 159/441 reads (36%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.928); catalogued as rs771133536; called by muse, mutect2, varscan2
- PTPRT | c.2073G>A p.W691* | Nonsense Mutation (SNP) | VAF 174/444 reads (39%) | catalogued as COSV61973521, COSV62032533; called by muse, mutect2, varscan2
- RUFY4 | c.408C>A p.S136R | Missense Mutation (SNP) | VAF 155/369 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs888461089; called by muse, mutect2, varscan2
- SCN9A | c.4892G>A p.R1631H (on ENST00000303354; = p.R1620H on NM_002977.3) | Missense Mutation (SNP) | VAF 255/675 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs201079869; called by muse, mutect2, varscan2
- SECISBP2 | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 208/324 reads (64%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as rs201887529; called by muse, mutect2, varscan2
- SERPINB7 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 213/550 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748771798, COSV60533682; called by muse, mutect2, varscan2
- SLC38A4 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 134/358 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as COSV99872967; called by muse, mutect2, varscan2
- SPTBN4 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 273/728 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as rs566193157, COSV100150834; called by muse, mutect2, varscan2
- STRC | c.3823G>A p.E1275K | Missense Mutation (SNP) | VAF 113/177 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV101348017; called by muse, mutect2, varscan2
- TMCO3 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 330/424 reads (78%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as rs1489865543; called by muse, varscan2
- TTN | c.12175G>A p.D4059N (on ENST00000591111; = p.D4013N on NM_003319.4) | Missense Mutation (SNP) | VAF 217/549 reads (40%) | catalogued as COSV100611906; called by muse, mutect2, varscan2
- UPF1 | c.2192C>T p.S731F (on ENST00000599848 / NM_001297549.2; = p.S720F on NM_002911.4) | Missense Mutation (SNP) | VAF 146/378 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1479019968; called by muse, mutect2, varscan2
- ZNF536 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 231/607 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62832261; called by muse, mutect2, varscan2
- ADAMTS6 | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 172/460 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2782C>G p.P928A | Missense Mutation (SNP) | VAF 245/377 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AHSA1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 111/343 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ATP1A2 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 141/359 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- BTRC | c.1474G>A p.D492N (on ENST00000370187 / NM_033637.4; = p.D456N on NM_003939.5) | Missense Mutation (SNP) | VAF 101/176 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPER3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 210/286 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDCA7L | c.141T>G p.F47L | Missense Mutation (SNP) | VAF 131/385 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CFTR | c.1222T>A p.L408I | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); called by muse, varscan2
- CHERP | c.2405C>T p.S802F | Missense Mutation (SNP) | VAF 254/606 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CHRNB1 | c.244-1G>A p.X82_splice | Splice Site (SNP) | VAF 147/363 reads (40%) | called by muse, mutect2, varscan2
- CSMD3 | c.6470C>T p.S2157F (on ENST00000297405 / NM_001363185.1; = p.S2053F on NM_052900.3) | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DCDC1 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 129/367 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DSEL | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 221/661 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DYRK2 | c.1577C>T p.P526L (on ENST00000344096 / NM_006482.3; = p.P453L on NM_003583.4) | Missense Mutation (SNP) | VAF 218/631 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXK1 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 218/564 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ILVBL | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 138/421 reads (33%) | called by muse, mutect2, varscan2
- KATNIP | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAPK8IP2 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 281/665 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MCCC1 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 177/522 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MELK | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 129/192 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NTF3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 246/616 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR13D1 | c.212T>A p.L71H | Missense Mutation (SNP) | VAF 176/267 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR7D2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 199/535 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- OSBPL8 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 153/378 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2G | c.4309-1G>A p.X1437_splice (on ENST00000676171; = p.X1396_splice on NM_004570.5) | Splice Site (SNP) | VAF 82/211 reads (39%) | called by muse, mutect2, varscan2
- PNRC1 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 92/439 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- PRKCQ | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PSMB11 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 251/659 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RIN2 | c.646G>A p.D216N (on ENST00000255006 / NM_001242581.1; = p.D167N on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/326 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SBK3 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 212/623 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SEPSECS | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- SGK2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 67/463 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SLC22A24 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 148/377 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SLC35A4 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 248/372 reads (67%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.1895T>A p.L632* | Nonsense Mutation (SNP) | VAF 84/241 reads (35%) | called by muse, mutect2, varscan2
- STK26 | c.128A>T p.D43V | Missense Mutation (SNP) | VAF 222/271 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- STRN3 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 180/443 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECTA | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 231/555 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- THADA | c.3788G>A p.R1263K | Missense Mutation (SNP) | VAF 129/229 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- USH1C | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM32 | c.1803G>A p.Q601= | Silent (SNP) | VAF 110/310 reads (35%) | called by muse, mutect2, varscan2
- ADGRB2 | c.1947C>T p.T649= | Silent (SNP) | VAF 386/501 reads (77%) | called by muse, mutect2, varscan2
- ADGRE1 | c.1842G>A p.L614= | Silent (SNP) | VAF 203/506 reads (40%) | catalogued as rs1233150009; called by muse, mutect2, varscan2
- ANAPC2 | c.867C>T p.F289= | Silent (SNP) | VAF 357/616 reads (58%) | called by muse, mutect2, varscan2
- CCR9 | c.270G>A p.L90= (on ENST00000357632 / NM_031200.3; = p.L78= on NM_006641.4) | Silent (SNP) | VAF 192/484 reads (40%) | catalogued as rs746631019; called by muse, mutect2, varscan2
- CFAP57 | c.3210G>A p.L1070= (on ENST00000372492 / NM_001378189.1; = p.L1103= on NM_001195831.3) | Silent (SNP) | VAF 191/542 reads (35%) | called by muse, mutect2, varscan2
- DACT2 | c.2106C>T p.S702= | Silent (SNP) | VAF 279/777 reads (36%) | catalogued as rs778690232; called by muse, mutect2, varscan2
- DHX38 | c.3234C>T p.F1078= | Silent (SNP) | VAF 141/386 reads (37%) | catalogued as rs757832101; called by muse, mutect2, varscan2
- DNAH1 | c.5502C>T p.N1834= | Silent (SNP) | VAF 137/342 reads (40%) | called by muse, mutect2, varscan2
- DNM1 | c.1164C>T p.I388= | Silent (SNP) | VAF 147/604 reads (24%) | called by muse, mutect2, varscan2
- DPH1 | c.930C>T p.A310= | Silent (SNP) | VAF 144/404 reads (36%) | called by muse, mutect2, varscan2
- DSC2 | c.636T>C p.I212= | Silent (SNP) | VAF 109/287 reads (38%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.984C>T p.D328= (on ENST00000450689 / NM_001142749.3; = p.D161= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 117/310 reads (38%) | catalogued as rs774408868, COSV51890019, COSV51890104; called by muse, mutect2, varscan2
- FAM83H | c.3004C>T p.L1002= | Silent (SNP) | VAF 311/1191 reads (26%) | catalogued as rs1554621805; called by muse, mutect2, varscan2
- FHOD3 | c.2874C>T p.I958= (on ENST00000359247 / NM_001281739.3; = p.I975= on NM_025135.5) | Silent (SNP) | VAF 164/479 reads (34%) | catalogued as rs778956050; called by muse, mutect2
- FREM3 | c.1098C>T p.T366= | Silent (SNP) | VAF 269/657 reads (41%) | catalogued as rs1423624925, COSV61679431; called by muse, mutect2, varscan2
- GULP1 | c.444A>T p.A148= | Silent (SNP) | VAF 146/400 reads (37%) | catalogued as rs549913208; called by muse, mutect2, varscan2
- HLA-DOB | c.807C>T p.L269= | Silent (SNP) | VAF 217/599 reads (36%) | catalogued as rs996616618, COSV71270828; called by muse, mutect2, varscan2
- HTR3A | c.1053C>T p.I351= | Silent (SNP) | VAF 213/518 reads (41%) | catalogued as rs756139701, COSV55467751; called by muse, mutect2, varscan2
- IGHM | c.429G>A p.Q143= | Silent (SNP) | VAF 203/531 reads (38%) | called by muse, mutect2, varscan2
- KCNJ8 | c.660C>T p.I220= | Silent (SNP) | VAF 186/475 reads (39%) | catalogued as COSV99557415; called by muse, mutect2, varscan2
- KIF5C | c.2832G>A p.G944= | Silent (SNP) | VAF 232/573 reads (40%) | catalogued as COSV101276079, COSV68480818; called by muse, mutect2, varscan2
- KSR2 | c.1551C>A p.S517= | Silent (SNP) | VAF 79/716 reads (11%) | catalogued as COSV100196400; called by muse, mutect2, varscan2
- LGALS12 | c.21G>A p.L7= | Silent (SNP) | VAF 144/440 reads (33%) | called by muse, mutect2, varscan2
- MC2R | c.456G>A p.T152= | Silent (SNP) | VAF 246/684 reads (36%) | catalogued as rs760107296, COSV100562837; called by muse, mutect2, varscan2
- MISP | c.1569C>T p.P523= | Silent (SNP) | VAF 277/757 reads (37%) | catalogued as rs766774963, COSV53122793; called by muse, mutect2, varscan2
- MYO7A | c.1956C>T p.C652= | Silent (SNP) | VAF 144/369 reads (39%) | catalogued as rs367693437; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCKIPSD | c.1948C>T p.L650= | Silent (SNP) | VAF 127/362 reads (35%) | catalogued as rs550799052; called by muse, mutect2, varscan2
- OOSP2 | c.297G>A p.R99= | Silent (SNP) | VAF 139/325 reads (43%) | catalogued as COSV53930065; called by muse, mutect2, varscan2
- SGK2 | c.1182C>T p.S394= | Silent (SNP) | VAF 162/565 reads (29%) | called by muse, varscan2
- SPATA18 | c.471C>T p.A157= | Silent (SNP) | VAF 143/345 reads (41%) | catalogued as rs1212187326, COSV99730230; called by muse, mutect2, varscan2
- ZNF644 | c.93A>C p.I31= | Silent (SNP) | VAF 119/328 reads (36%) | called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532264 C>T | 5'Flank (SNP) | VAF 190/438 reads (43%) | catalogued as COSV101587919; called by muse, mutect2, varscan2
- CPLANE1 | c.*5313A>T | 3'UTR (SNP) | VAF 120/376 reads (32%) | called by muse, mutect2, varscan2
- RAB15 | c.324+49G>A | Intron (SNP) | VAF 198/576 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.34354+1149C>T | Intron (SNP) | VAF 96/274 reads (35%) | catalogued as rs1233379856; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBR3 | c.-1C>T | 5'UTR (SNP) | VAF 164/445 reads (37%) | catalogued as rs1222820908; called by muse, mutect2, varscan2
